Somatic mutation profile of tumor specimen TCGA-ER-A3EV-06A (aliquot TCGA-ER-A3EV-06A-11D-A20D-08) from TCGA case TCGA-ER-A3EV, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.8 years (21,099 days).
Specimen TCGA-ER-A3EV-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37e51281-2c27-4a16-b660-6db01c24307f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A3EV-10A (Blood Derived Normal), aliquot TCGA-ER-A3EV-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deeae810-ef70-4a3b-a4ef-c1e81b95ad31

The open-access MAF lists 85 somatic variants for this specimen: 67 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 61, Silent 18, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM28 | c.2141G>A p.R714K | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56103465; called by muse, mutect2, varscan2
- ADAMTS5 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs766100243, COSV53182969; called by muse, mutect2, varscan2
- ADCY10 | c.4292C>T p.A1431V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV63243485; called by muse, mutect2, varscan2
- APC2 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs746073662, COSV52020255, COSV99279190; called by muse, mutect2, varscan2
- ARL14EP | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV56343311; called by muse, mutect2, varscan2
- ATP11A | c.542C>G p.A181G | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV52119390; called by muse, mutect2, varscan2
- C4orf19 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 69/342 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs111504567, COSV52649985; called by muse, mutect2, varscan2
- CCDC178 | c.2219A>C p.K740T (on ENST00000383096 / NM_001105528.3; = p.K702T on NM_198995.3) | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV55788697; called by muse, mutect2, varscan2
- CCDC93 | c.1324A>T p.T442S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV60123124; called by muse, mutect2, varscan2
- CCT2 | c.1582C>G p.R528G | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54741099; called by muse, mutect2, varscan2
- CENPF | c.1829A>C p.E610A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV65277547; called by muse, mutect2, varscan2
- CENPJ | c.1591G>C p.G531R | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.64); catalogued as COSV67883947; called by muse, mutect2, varscan2
- CEP126 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV54828861; called by muse, mutect2
- CLDN2 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 79/102 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61021082, COSV61021340; called by muse, mutect2, varscan2
- CLN8 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1269674233, COSV58671209; called by muse, mutect2, varscan2
- COL11A2 | c.2989-1G>A p.X997_splice (on ENST00000341947 / NM_080680.3; = p.X890_splice on NM_080679.2) | Splice Site (SNP) | VAF 44/611 reads (7%) | catalogued as COSV59500529; called by muse, mutect2
- COL20A1 | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.576); catalogued as rs1232761514, COSV58924094; called by muse, mutect2, varscan2
- COPA | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 167/225 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54107265; called by muse, mutect2, varscan2
- DBNL | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68881881; called by muse, mutect2, varscan2
- DHRSX | c.164T>G p.I55S | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58137238; called by muse, mutect2, varscan2
- DHX30 | c.1063C>G p.L355V (on ENST00000445061 / NM_138615.3; = p.L316V on NM_014966.3) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as COSV53140894; called by muse, mutect2, varscan2
- DMD | c.4327C>T p.Q1443* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV63778537; called by muse, mutect2, varscan2
- DYSF | c.4331C>G p.P1444R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.254); catalogued as rs1367340192, COSV50513809, COSV99243330; called by muse, mutect2, varscan2
- ELAC1 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53997005; called by muse, mutect2, varscan2
- EVC2 | c.3846G>C p.E1282D | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV60390722, COSV60398334, COSV60399248; called by muse, mutect2, varscan2
- FBXO27 | c.657C>G p.F219L | Missense Mutation (SNP) | VAF 94/445 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV53072881, COSV53073029; called by muse, mutect2, varscan2
- FRMPD4 | c.1581C>G p.N527K | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV66216707, COSV66220470; called by muse, mutect2, varscan2
- GATA2 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV62005905; called by muse, mutect2, varscan2
- GIMAP7 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV57960216; called by muse, mutect2, varscan2
- GLRA1 | c.252+1G>C p.X84_splice | Splice Site (SNP) | VAF 35/97 reads (36%) | catalogued as COSV51021392; called by muse, mutect2, varscan2
- GPR119 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as rs771380953, COSV52276324; called by muse, mutect2, varscan2
- IGSF8 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV58758820; called by muse, mutect2, varscan2
- INO80D | c.2491G>T p.D831Y | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as COSV68958674, COSV68959704; called by muse, mutect2, varscan2
- JUND | c.832A>G p.N278D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53254826; called by muse, mutect2, varscan2
- KAT6A | c.2056C>G p.L686V | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55910184; called by muse, mutect2, varscan2
- KISS1 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.64); PolyPhen benign (0.085); catalogued as COSV65817092; called by muse, mutect2, varscan2
- LRRC4C | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs138717868; called by muse, mutect2, varscan2
- LSM14A | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV70885520; called by muse, mutect2, varscan2
- MAS1L | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV65809428; called by muse, mutect2
- METTL8 | c.302T>C p.F101S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64550937; called by muse, mutect2, varscan2
- MMP13 | c.1151C>G p.A384G | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV52824961; called by muse, mutect2
- MYBPC1 | c.1183G>T p.G395C (on ENST00000550270 / NM_206820.2; = p.G420C on NM_002465.4) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752444069, COSV62256037; called by muse, mutect2, varscan2
- NEXMIF | c.4178G>A p.R1393K | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV50067762; called by muse, mutect2, varscan2
- NLRP8 | c.2080G>C p.D694H | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV52590108, COSV52591703; called by muse, mutect2, varscan2
- PCDH15 | c.4754G>A p.C1585Y (on ENST00000644397 / NM_001354429.2; = p.C1527Y on NM_001142771.2) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.544); catalogued as rs1290443489, COSV64700051, COSV64719601; called by muse, mutect2, varscan2
- PDE1B | c.1001C>G p.T334R | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54494939; called by muse, mutect2, varscan2
- PKN2 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV65144029; called by muse, mutect2, varscan2
- PLXNA3 | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63755053; called by muse, mutect2, varscan2
- PRPF6 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV53875786; called by muse, mutect2, varscan2
- RIPOR1 | c.2806C>T p.R936W (on ENST00000379312 / NM_001193522.2; = p.R932W on NM_024519.4) | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200080940, COSV50243155; called by muse, mutect2, varscan2
- SCN8A | c.2516G>C p.G839A | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61989150; called by muse, mutect2, varscan2
- SDCCAG8 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV59405956, COSV59412183; called by muse, mutect2, varscan2
- SF3A1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53170521; called by muse, mutect2, varscan2
- SIGLEC5 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.593); catalogued as COSV99706892; called by muse, mutect2
- TCHH | c.5660G>C p.R1887P | Missense Mutation (SNP) | VAF 142/646 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.418); catalogued as rs201952511, COSV64278390; called by muse, mutect2
- TENM4 | c.5992C>G p.L1998V | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV53654730; called by muse, mutect2
- TNC | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747156650, COSV60788523; called by muse, mutect2, varscan2
- TPCN1 | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV59238148; called by muse, mutect2, varscan2
- TRPS1 | c.3391G>A p.V1131M (on ENST00000220888 / NM_001330599.2; = p.V1144M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.813); catalogued as rs1180274964, COSV55249833; called by muse, mutect2, varscan2
- TRPS1 | c.1750C>T p.P584S (on ENST00000220888 / NM_001330599.2; = p.P597S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV55237479, COSV55254966; called by muse, mutect2, varscan2
- TTC13 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1185397535, COSV64169477, COSV64169603; called by muse, mutect2
- UVRAG | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 39/919 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.617); catalogued as rs200407197, COSV62108074, COSV62108778; called by muse, mutect2
- ZNF251 | c.1663C>A p.L555M | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV52958524; called by muse, mutect2, varscan2
- ZNF513 | c.1160C>A p.P387H | Missense Mutation (SNP) | VAF 49/321 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52009463; called by muse, mutect2, varscan2
- ZNF831 | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs767254726, COSV64043485, COSV64044869; called by muse, mutect2, varscan2
- DLC1 | c.4076_4077dup p.S1360* (on ENST00000276297 / NM_001348081.2; = p.S923* on NM_006094.5) | Frame Shift Ins (INS) | VAF 26/86 reads (30%) | called by mutect2, pindel, varscan2
- SGSM2 | c.2726_2728del p.Y909del (on ENST00000426855 / NM_001098509.2; = p.Y954del on NM_014853.3) | In Frame Del (DEL) | VAF 18/133 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD34A | c.726C>G p.L242= | Silent (SNP) | VAF 127/477 reads (27%) | catalogued as COSV60161717; called by muse, mutect2, varscan2
- ASTN1 | c.2235G>C p.L745= | Silent (SNP) | VAF 90/645 reads (14%) | catalogued as COSV56078826; called by muse, varscan2
- CATSPERD | c.1125G>A p.A375= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs373116853, COSV100486922; called by muse, varscan2
- CHD7 | c.6966C>T p.N2322= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV71113292; called by muse, mutect2
- EXOC4 | c.1671T>C p.P557= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV54113514; called by muse, mutect2, varscan2
- KBTBD2 | c.1293T>C p.I431= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as COSV58364049; called by muse, mutect2, varscan2
- MST1R | c.2604C>A p.A868= | Silent (SNP) | VAF 9/228 reads (4%) | catalogued as COSV56572047; called by muse, mutect2
- PCDHB3 | c.2134C>A p.R712= | Silent (SNP) | VAF 110/368 reads (30%) | catalogued as COSV50606756; called by muse, mutect2, varscan2
- PPTC7 | c.519A>C p.S173= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as COSV62826814; called by muse, mutect2, varscan2
- PTCHD4 | c.2121C>T p.N707= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs780216605, COSV59787068; called by muse, mutect2, varscan2
- RP1 | c.1056T>C p.T352= | Silent (SNP) | VAF 19/239 reads (8%) | catalogued as COSV55123157; called by muse, mutect2
- TCF19 | c.304C>T p.L102= | Silent (SNP) | VAF 65/245 reads (27%) | catalogued as COSV52564559; called by muse, mutect2, varscan2
- THBS3 | c.2706G>A p.A902= | Silent (SNP) | VAF 22/280 reads (8%) | catalogued as rs146591443; called by muse, mutect2
- TSKU | c.786G>A p.S262= | Silent (SNP) | VAF 20/354 reads (6%) | catalogued as rs147023916; called by muse, mutect2
- ZBTB25 | c.597C>T p.P199= | Silent (SNP) | VAF 124/315 reads (39%) | catalogued as COSV67198878; called by muse, mutect2, varscan2
- ZFHX4 | c.2700G>A p.A900= | Silent (SNP) | VAF 30/205 reads (15%) | catalogued as COSV51482345; called by muse, mutect2, varscan2
- ZFP28 | c.1179T>C p.H393= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56737351; called by muse, mutect2, varscan2
- ZNF775 | c.1347C>T p.N449= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV61613052; called by muse, mutect2
